FM case AD7245 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/43614c1a-4e09-49ed-bb4c-9e0b9bbf9641

Female, 44.1 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the uterus; metastasis biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
